Somatic mutation profile of tumor specimen 0DFXGZ from CCDI case PBBSCK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Age at diagnosis: 16.2 years (5,919 days).
Specimen 0DFXGZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8291202e-3df7-4bca-98cc-6391bdcb6e0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFXEY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ed9e17c-15ac-4c1f-912a-0166947c32a5

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IFNA6 | c.242A>G p.H81R | Missense Mutation (SNP) | VAF 233/1397 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV66506173; called by muse, mutect2, varscan2
- SDK2 | c.3074G>A p.R1025H | Missense Mutation (SNP) | VAF 136/1220 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs766565174; called by muse, mutect2, varscan2
- AL159163.1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 166/776 reads (21%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- OR2T11 | c.295T>C p.F99L | Missense Mutation (SNP) | VAF 408/2037 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- OR6V1 | c.314T>A p.L105Q | Missense Mutation (SNP) | VAF 289/1302 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BCAP31 | c.93-13G>A | Intron (SNP) | VAF 380/1086 reads (35%) | catalogued as rs1249181911; called by muse, mutect2, varscan2
- ETFB | c.58-93G>A | Intron (SNP) | VAF 203/963 reads (21%) | called by muse, mutect2, varscan2
- ZNF738 | chr19:21383511 G>A | 3'Flank (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
